Surgical pathology report (de-identified scan), TCGA case TCGA-DD-A1EG, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-A1EG-01A (Primary Tumor).

[page 1 of 4]
ICD-0-3
Carcinoma, hepatocellular, NOS
8170/3
Site Code: Liver C22.0
1/19/11 *lw*

Patient Key:
Surgical date:

TISSUE DESCRIPTION:

... eived in formalin labeled "segment 4A liver" is a fragment of liver measuring 3.0 x 1.4 x 1.0 cm. The specimen is a wedge resection and triangular in shape. There is cautery artifact on one side, the capsule is smooth and without abnormalities on another surface, and the cut surface is golden yellow. The specimen is serially sectioned and submitted in cassettes A1 and A2.

DIAGNOSIS:

Liver, segment 4A, wedge biopsy: Fatty liver disease characterized by marked steatosis, mildly active (grade 1 of 3) steatohepatitis, and periportal fibrosis with rare bridging (stage 2-3 of 4).

DIAGNOSIS COMMENT:

This is a large wedge biopsy with numerous portal tracts, although the cytology is distorted by moderate to marked cautery artifact. Portal areas show intact bile ducts with mild nonspecific lymphocytic inflammation and several bile duct hamartomas (von Meyenburg complexes). Acinar parenchyma shows marked, nearly panacinar, steatosis that is accompanied by only rare ballooned hepatocytes and very spotty lymphohistiocytic infiltrates. There is no well-formed Mallory's hyaline. Iron and PAS-D stains are negative. Trichrome and reticulin stains show only slight zone 3 fibrosis, but fairly extensive periportal fibrosis and a rare portal-portal bridge. There is no evidence of extensive fibrosis or cirrhosis.

Addendum/Procedure included

TISSUE DESCRIPTION:
liver (6.2 x 5.0 x 4.8 cm).

Tissue from

DIAGNOSIS:

Liver, segment 4A/4B, resection: Hepatocellular carcinoma, grade 3 (of 4), forming a 3.1 x 2.5 x 1.8 cm mass. The surgical resection margin is negative. Vascular invasion is not identified.

The section of the non-neoplastic hepatic parenchyma demonstrates severe, predominantly macrovesicular steatosis with a moderately active steatohepatitis and periportal and focal bridging fibrosis (stage 2-3 of 4). Scattered non-

[page 2 of 4]
necrotizing portal and lobular granulomas are also seen (see comment).

Comment: The section of non-neoplastic liver contains numerous portal tracts for evaluation. Many of these contain mild to moderate lymphocytic inflammatory infiltrates. Some also contain granulomatous inflammation. The latter does not appear to be directed at bile ducts. There is no significant interface activity. The lobular parenchyma demonstrates severe, predominantly macrovesicular steatosis. Lobular inflammation, occasional neutrophils, occasional microgranulomas, and hepatocyte ballooning are seen. A trichrome stain confirms the presence of periportal and focal bridging fibrosis. The iron stain is negative for hemosiderosis.

Results of GMS and Auramine-rhodamine stains will be reported as an addendum. Given the clinical scenario, the granulomatous inflammation may represent reaction to the patient's neoplasm. Clinical correlation is needed.

ADDENDUM:

Special stains for microorganisms (AR and GMS) are negative.

AMENDMENTS: Revision Description: Amended to include non-neoplastic liver component in final diagnosis.

....Original Diagnosis....

Liver, segment 4A/4B, resection: Hepatocellular carcinoma, grade 3 (of 4), forming a 3.1 x 2.5 x 1.8 cm mass, 0.1 cm from the surgical margin. The surgical resection margin is negative. Vascular invasion is not identified. Evaluation of the non-neoplastic liver parenchyma will be reported in an addendum.

PRELIMINARY FROZEN SECTION CONSULTATION:

Liver, segment 4A/4B, resection: Hepatocellular carcinoma. Surgical margin is negative. Non-neoplastic liver shows marked steatosis. Defer to permanent sections for further assessment.

[page 3 of 4]
Liver • Digestive System CAP Approved

* Data elements *with asterisks* are *not required* for accreditation purposes for the Commission on Cancer. These elements may be clinically important, but are not yet validated or regularly used in patient management. Alternatively, the necessary data may not be available to the pathologist at the time of pathologic assessment of this specimen.

LIVER: ResectionPatient name: *(to be de-identified)*

Surgical pathology number:

MACROSCOPIC**Specimen Type**

- ☒ Right lobectomy
☐ Extended right lobectomy
☐ Medial segmentectomy
☐ Left lateral segmentectomy
☐ Total left lobectomy
☐ Explanted liver
☐ Other (specify): _____
☐ Not specified

Focality

- ☒ Solitary (specify location): Segment 6A/143
☐ Multiple (specify location): _____

Tumor SizeGreatest dimension: 2.1 cm*Additional dimensions: 1.2 x 1.8 cm☐ Cannot be determined (see Comment)**MICROSCOPIC****Histologic Type**

- ☒ Hepatocellular carcinoma
☐ Fibrolamellar hepatocellular carcinoma variant (specify): _____
☐ Combined hepatocellular and cholangiocarcinoma
☐ Cholangiocarcinoma, intrahepatic
☐ Bile duct cystadenocarcinoma
☐ Undifferentiated carcinoma
☐ Other (specify): _____
☐ Carcinoma, type cannot be determined

Histologic Grade

- ☐ Not applicable
☐ GX: Cannot be assessed
☐ GI: Well differentiated
☐ GII: Moderately differentiated
☒ GIII: Poorly differentiated
☐ GIV: Undifferentiated/anaplastic
☐ Other (specify): _____

[page 4 of 4]
Pathologic Staging (pTNM)

Primary Tumor (pT)

- ☐ pTX: Cannot be assessed
☐ pT0: No evidence of primary tumor
☒ pT1: Solitary tumor with no vascular invasion
☐ pT2: Solitary tumor with vascular invasion or multiple tumors none more than 5 cm
☐ pT3: Multiple tumors more than 5 cm or tumor involving a major branch of the portal or hepatic vein(s)
☐ pT4: Tumor(s) with direct invasion of adjacent organs other than the gallbladder or perforation of visceral peritoneum

Regional Lymph Nodes (pN)

- ☒ pNX: Cannot be assessed
☐ pN0: No regional lymph node metastasis
☐ pN1: Regional lymph node metastasis

Specify: Number examined: ____

Number involved: ____

Distant Metastasis (pM)

- ☒ pMX: Cannot be assessed
☐ pM1: Distant metastasis

*Specify site(s), if known: _____

Margins (check all that apply)

Parenchymal Margin

- ☐ Cannot be assessed
☒ Uninvolved by invasive carcinoma
Distance of invasive carcinoma from closest margin: 10 mm
Specify margin: _____

☐ Involved by invasive carcinoma

Bile Duct Margin (Cholangiocarcinoma Only)

- ☒ Cannot be assessed
☐ Uninvolved by invasive carcinoma
* ☐ Carcinoma in situ absent
* ☐ Carcinoma in situ present
☐ Involved by invasive carcinoma

Other Margin

Specify margin: _____

- ☐ Cannot be assessed
☐ Uninvolved by invasive carcinoma
☐ Involved by invasive carcinoma

***Venous (Large Vessel) Invasion (V)**

- * ☐ Absent
* ☐ Present
* ☒ Indeterminate

***Additional Pathologic Findings (check all that apply)**

- * ☐ None identified
* ☐ Hepatocellular dysplasia
* ☐ Ductal dysplasia
* ☐ Cirrhosis/fibrosis
* ☐ Iron overload
* ☐ Hepatitis (specify type): _____
* ☒ Other (specify): steatosis, severe

bridging fibrosisNecrotizing portal & lobular granulomas

Source: NCI Genomic Data Commons file 00fe7317-863d-4149-8416-f3fd307a02cf (TCGA-DD-A1EG.D3F371AB-487A-47A8-8EE7-2D27D62FE482.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).